Somatic mutation profile of tumor specimen MP2PRT-PAVKND-TMP1-A (aliquot MP2PRT-PAVKND-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVKND, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.7 years (2,436 days).
Specimen MP2PRT-PAVKND-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7877bf45-504e-4a84-9c30-78717f5c7407.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVKND-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVKND-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4c775f6-90c2-4f9f-98a8-1c6e40cb52d1

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX15 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61028395; called by muse, mutect2
- DOCK3 | c.1505G>T p.G502V | Missense Mutation (SNP) | VAF 43/331 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs771056800, COSV56500774; called by muse, mutect2, varscan2
- ERVW-1 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 103/296 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs762644633; called by muse, mutect2, varscan2
- FILIP1 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 90/277 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs776455963, COSV52725973; called by muse, mutect2, varscan2
- RPL3L | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 148/463 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs142332527, COSV51906997; called by muse, mutect2, varscan2
- SETD1B | c.3386C>T p.A1129V | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV57349993; called by muse, mutect2, varscan2
- ST8SIA2 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 41/600 reads (7%) | PolyPhen possibly damaging (0.901); catalogued as rs201692548, COSV51566823; called by muse, mutect2
- SYT10 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 109/394 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs375066285, COSV57338173; called by muse, mutect2, varscan2
- APBA2 | c.1993C>T p.P665S | Missense Mutation (SNP) | VAF 133/450 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CD101 | c.2180T>A p.I727N | Missense Mutation (SNP) | VAF 93/334 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FHOD3 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 168/462 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FSIP2 | c.7590T>A p.S2530R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLB1L2 | c.15C>A p.S5R | Missense Mutation (SNP) | VAF 137/454 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1-69 | chr14:106714657 del TCAGGATGTGGGTTTTCACACTGTGTCTCTCGCACAGTAATA | Missense Mutation (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel*
- IGHV3-13 | c.348_350delinsCTATCACCCCC p.R116Sfs*? | Frame Shift Ins (INS) | VAF 26/62 reads (42%) | called by pindel, varscan2*
- MMP9 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 79/300 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.23846G>A p.R7949H | Missense Mutation (SNP) | VAF 90/610 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- PTPRR | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF4 | c.2170C>T p.L724F | Missense Mutation (SNP) | VAF 183/514 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- WDR87 | c.3455A>G p.D1152G | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.22); called by muse, mutect2
- ACR | c.1203C>T p.S401= | Silent (SNP) | VAF 30/185 reads (16%) | catalogued as rs3915510; called by muse, mutect2, varscan2
- CCSER1 | c.498A>G p.E166= | Silent (SNP) | VAF 21/317 reads (7%) | called by muse, mutect2
- FUNDC1 | c.18C>T p.P6= | Silent (SNP) | VAF 194/290 reads (67%) | called by muse, mutect2, varscan2
- HIVEP2 | c.1815C>T p.H605= | Silent (SNP) | VAF 88/553 reads (16%) | catalogued as rs888890754; called by muse, mutect2, varscan2
- PABPC4L | c.189T>C p.D63= | Silent (SNP) | VAF 138/394 reads (35%) | called by muse, mutect2, varscan2
- UACA | c.1377C>T p.D459= | Silent (SNP) | VAF 100/348 reads (29%) | catalogued as rs537236890, COSV59856611; called by muse, mutect2, varscan2
